Somatic mutation profile of tumor specimen C3N-00180-02 (aliquot CPT0066780006) from CPTAC case C3N-00180, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.5 years (20,625 days).
Specimen C3N-00180-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd180b45-6735-428e-bcbc-37e828a8cd6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00180-31 (Blood Derived Normal), aliquot CPT0071670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9c7851e-4607-4f00-b179-7ef995b47a83

The open-access MAF lists 155 somatic variants for this specimen: 103 protein-altering or splice-affecting, 32 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 32, Intron 9, Nonsense Mutation 8, Splice Site 5, 5'UTR 5, RNA 5, Frame Shift Del 4, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 109/316 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDHA10 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 438/977 reads (45%) | hotspot (GDC flag); SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs201104305, COSV56514051; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 289/468 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRA1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs762350276; called by muse, mutect2, varscan2
- ASTN1 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56061957, COSV56086029; called by muse, mutect2, varscan2
- B3GAT1 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 181/211 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV56997599; called by muse, mutect2, varscan2
- CLCA4 | c.2553C>G p.S851R | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as rs1489823190; called by muse, mutect2, varscan2
- COL5A3 | c.2938G>A p.G980S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759353874; called by muse, mutect2, varscan2
- CSMD2 | c.9559+1G>A p.X3187_splice | Splice Site (SNP) | VAF 53/109 reads (49%) | catalogued as COSV53910136; called by muse, mutect2, varscan2
- ESPL1 | c.5330G>C p.W1777S | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57757300; called by muse, mutect2, varscan2
- GAK | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV58511036; called by muse, mutect2, varscan2
- GALNT14 | c.827G>T p.R276M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs1278209657, COSV100204318; called by muse, mutect2, varscan2
- IBSP | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1448153545; called by muse, mutect2, varscan2
- KIAA0825 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56947803; called by muse, mutect2, varscan2
- LTN1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100798305; called by muse, mutect2, varscan2
- MIA3 | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.232); catalogued as rs570612707; called by muse, mutect2, varscan2
- MYO5B | c.2684G>T p.R895L | Missense Mutation (SNP) | VAF 293/415 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53216168, COSV99545631; called by muse, mutect2, varscan2
- NDST3 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV56614255; called by muse, mutect2, varscan2
- NLRP4 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.682); catalogued as rs574342762; called by muse, mutect2, varscan2
- OBSCN | c.8344C>T p.R2782C | Missense Mutation (SNP) | VAF 152/319 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041621354, COSV52747720; called by muse, mutect2, varscan2
- OR2G2 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV60742276; called by muse, mutect2, varscan2
- POM121L12 | c.576C>G p.F192L | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV68692173; called by muse, varscan2
- RTN1 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV50722451, COSV50724581; called by muse, mutect2, varscan2
- SASS6 | c.1450G>C p.V484L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs367882680; called by muse, mutect2, varscan2
- SNCAIP | c.2521G>A p.G841S | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV54410683; called by muse, mutect2
- TENM1 | c.7777G>T p.G2593W | Missense Mutation (SNP) | VAF 77/98 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64435116; called by muse, mutect2, varscan2
- TET2 | c.3523A>G p.I1175V | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.784); catalogued as COSV54409071, COSV54418428; called by muse, mutect2, varscan2
- THOP1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs141596601; called by muse, mutect2, varscan2
- UGT2B10 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs752465166; called by muse, varscan2
- USO1 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV53705273; called by muse, mutect2, varscan2
- WASHC2C | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 82/343 reads (24%) | catalogued as COSV60493053; called by muse, mutect2, varscan2
- ADGRL3 | c.4438G>T p.D1480Y (on ENST00000506720 / NM_001322402.2; = p.D1369Y on NM_015236.6) | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ALPI | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 157/409 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ALS2CL | c.103+1G>T p.X35_splice | Splice Site (SNP) | VAF 92/158 reads (58%) | called by muse, mutect2, varscan2
- ALYREF | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- AMER3 | c.1765A>T p.T589S | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARNT2 | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASIC2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ATAD5 | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BDP1 | c.908G>T p.W303L | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRWD3 | c.1651-1G>T p.X551_splice | Splice Site (SNP) | VAF 95/122 reads (78%) | called by muse, mutect2, varscan2
- C7 | c.1826C>A p.P609Q | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CENPE | c.7249A>G p.I2417V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP221 | c.2404A>T p.R802W | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CHD9 | c.4835A>G p.Q1612R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, varscan2
- CYLD | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.1462A>G p.R488G (on ENST00000409039; = p.R427G on NM_207437.3) | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DYNC1H1 | c.4669A>G p.I1557V | Missense Mutation (SNP) | VAF 20/726 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- EPCAM | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 223/670 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ERICH1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FASLG | c.382del p.E128Rfs*4 | Frame Shift Del (DEL) | VAF 185/370 reads (50%) | called by mutect2, pindel, varscan2
- FAT3 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 424/518 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRAS1 | c.11549G>T p.R3850L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSCB | c.2154_2155delinsT p.P719Hfs*7 | Frame Shift Del (DEL) | VAF 69/346 reads (20%) | called by pindel, varscan2*
- GAB4 | c.1484C>A p.A495E | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- GPRASP1 | c.3481T>A p.L1161I | Missense Mutation (SNP) | VAF 109/132 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HCN1 | c.2168C>A p.T723N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- IGKV3-11 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 245/665 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KCND2 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- L3MBTL4 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 36/46 reads (78%) | called by muse, mutect2, varscan2
- LAMA5 | c.5992_5993del p.T1998Hfs*54 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by pindel, varscan2
- LINC00632 | n.68+1G>T | Splice Site (SNP) | VAF 40/52 reads (77%) | called by muse, mutect2, varscan2
- LRCH4 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- LRRC74B | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MAP1B | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINK1 | c.2519del p.G840Afs*104 | Frame Shift Del (DEL) | VAF 18/31 reads (58%) | called by mutect2, pindel*
- MUC5B | c.11926C>A p.L3976M | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NALCN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 76/120 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- NEDD8 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFKBIZ | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NPBWR2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPA1 | c.2464G>T p.V822L (on ENST00000361510 / NM_130837.3; = p.V767L on NM_015560.3) | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8B3 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 178/331 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OTX1 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH8 | c.2028C>A p.D676E | Missense Mutation (SNP) | VAF 66/89 reads (74%) | SIFT tolerated (0.93); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PCLO | c.11678C>G p.P3893R | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PTCHD3 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RFTN2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- RPS9 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- RRP8 | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 465/609 reads (76%) | called by muse, mutect2, varscan2
- SDK2 | c.2647A>T p.S883C | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SKP1P2 | n.438+2G>A | Splice Site (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- SLC16A9 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SLCO1C1 | c.32T>A p.L11* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- SORCS1 | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 93/241 reads (39%) | called by muse, mutect2, varscan2
- SPATC1 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD3 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STK11 | c.710A>T p.D237V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEDC2 | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TMEM119 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TMEM237 | c.635G>T p.W212L (on ENST00000409883 / NM_001044385.3; = p.W204L on NM_152388.4) | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMTC1 | c.2598G>T p.L866F (on ENST00000539277 / NM_001193451.2; = p.L758F on NM_175861.3) | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNR | c.3968G>T p.W1323L | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE | c.508C>A p.L170M (on ENST00000618007 / NM_199261.4; = p.L152M on NM_199259.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPM5 | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 61/100 reads (61%) | called by muse, mutect2, varscan2
- USP19 | c.2252T>G p.V751G | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- USP19 | c.2251G>T p.V751L | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- VASH1 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZDHHC11 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZDHHC17 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ZFHX4 | c.5884A>T p.K1962* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- ZNF530 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF99 | c.2246C>A p.T749N | Missense Mutation (SNP) | VAF 115/193 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ACD | c.1566C>T p.P522= (on ENST00000620338; = p.P433= on NM_022914.3) | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs777330256; called by muse, mutect2
- ALPI | c.54G>A p.L18= | Silent (SNP) | VAF 156/410 reads (38%) | catalogued as rs1482050975; called by muse, mutect2, varscan2
- AMY2A | c.423T>C p.F141= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1336382319, COSV70214922; called by mutect2, varscan2
- AP5M1 | c.831T>C p.S277= | Silent (SNP) | VAF 127/434 reads (29%) | catalogued as rs1015179651; called by muse, mutect2, varscan2
- C4orf54 | c.4485C>G p.P1495= | Silent (SNP) | VAF 59/168 reads (35%) | called by muse, mutect2, varscan2
- CDH20 | c.2109C>A p.P703= | Silent (SNP) | VAF 108/148 reads (73%) | catalogued as rs139351388, COSV53004309, COSV53004918; called by muse, mutect2, varscan2
- CSMD3 | c.9984C>A p.T3328= (on ENST00000297405 / NM_001363185.1; = p.T3159= on NM_052900.3) | Silent (SNP) | VAF 74/207 reads (36%) | catalogued as rs1403867663, COSV52152274; called by muse, mutect2, varscan2
- DNAH14 | c.6726A>C p.A2242= (on ENST00000445597; = p.A2895= on NM_001367479.1) | Silent (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- DOCK4 | c.1629C>G p.L543= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- DYSF | c.951C>A p.L317= | Silent (SNP) | VAF 212/506 reads (42%) | catalogued as COSV50455140; called by muse, mutect2, varscan2
- FAM83H | c.909C>T p.A303= | Silent (SNP) | VAF 88/216 reads (41%) | catalogued as rs782396466; called by muse, mutect2, varscan2
- FBXO3 | c.339G>T p.R113= | Silent (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- HELZ2 | c.5475G>C p.T1825= (on ENST00000467148 / NM_001037335.2; = p.T1256= on NM_033405.3) | Silent (SNP) | VAF 85/216 reads (39%) | catalogued as rs775745654; called by muse, mutect2, varscan2
- HS3ST4 | c.1011G>T p.A337= | Silent (SNP) | VAF 121/393 reads (31%) | catalogued as COSV100499813, COSV100502128; called by muse, mutect2, varscan2
- JAKMIP2 | c.2115A>G p.R705= | Silent (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- KCNQ2 | c.501G>T p.P167= | Silent (SNP) | VAF 99/329 reads (30%) | catalogued as rs1435866317; called by muse, mutect2, varscan2
- LRRC40 | c.16C>A p.R6= | Silent (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- MAP3K4 | c.4419A>C p.S1473= | Silent (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- NACA2 | c.486A>G p.V162= | Silent (SNP) | VAF 218/529 reads (41%) | called by muse, mutect2, varscan2
- NDUFV3 | c.30A>G p.G10= | Silent (SNP) | VAF 111/295 reads (38%) | called by muse, mutect2, varscan2
- NUP42 | c.39C>A p.R13= | Silent (SNP) | VAF 96/270 reads (36%) | called by muse, mutect2, varscan2
- PEX2 | c.93G>A p.Q31= | Silent (SNP) | VAF 37/99 reads (37%) | called by muse, mutect2, varscan2
- PHLDB1 | c.870C>T p.S290= | Silent (SNP) | VAF 181/220 reads (82%) | catalogued as rs138784811; called by muse, mutect2, varscan2
- PKD1 | c.3711G>A p.T1237= | Silent (SNP) | VAF 80/631 reads (13%) | catalogued as rs775379313; called by muse, mutect2, varscan2
- PTPRU | c.333G>C p.G111= | Silent (SNP) | VAF 89/198 reads (45%) | called by muse, mutect2, varscan2
- RXFP1 | c.954G>T p.L318= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1806T>A p.A602= | Silent (SNP) | VAF 104/216 reads (48%) | called by muse, mutect2, varscan2
- SYNC | c.339G>A p.T113= | Silent (SNP) | VAF 134/365 reads (37%) | catalogued as rs749615976; called by muse, mutect2, varscan2
- THSD7B | c.3327G>T p.L1109= (on ENST00000272643; = p.L1107= on NM_001316349.2) | Silent (SNP) | VAF 75/194 reads (39%) | called by muse, mutect2, varscan2
- ZNF300 | c.588A>C p.P196= | Silent (SNP) | VAF 57/173 reads (33%) | called by muse, mutect2, varscan2
- ZNF541 | c.363C>G p.T121= | Silent (SNP) | VAF 166/402 reads (41%) | called by muse, mutect2, varscan2
- ZNF586 | c.27G>A p.A9= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as rs781215956; called by muse, mutect2, varscan2
- ANKRD26P1 | n.246G>C | RNA (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-411C>A | 5'UTR (SNP) | VAF 88/202 reads (44%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1029G>T | Intron (SNP) | VAF 65/93 reads (70%) | called by muse, mutect2, varscan2
- CHIA | c.-113C>A | 5'UTR (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- CSNK1D | c.187+47del | Intron (DEL) | VAF 170/445 reads (38%) | called by mutect2, pindel*, varscan2
- FAM86DP | n.831G>T | RNA (SNP) | VAF 264/582 reads (45%) | called by muse, mutect2, varscan2
- FBXO3 | c.359-4646C>T | Intron (SNP) | VAF 38/84 reads (45%) | catalogued as rs1341781905; called by muse, mutect2, varscan2
- FOSL2 | c.-8C>T | 5'UTR (SNP) | VAF 124/339 reads (37%) | catalogued as rs766714855; called by muse, mutect2, varscan2
- GRIA2 | c.2406+490G>C | Intron (SNP) | VAF 66/222 reads (30%) | catalogued as rs1422211484, COSV52392025; called by muse, mutect2, varscan2
- KANSL2 | c.1348-340G>A | Intron (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- OR51F5P | n.302G>T | RNA (SNP) | VAF 115/173 reads (66%) | called by muse, mutect2, varscan2
- RXFP1 | c.537-1445G>A | Intron (SNP) | VAF 46/154 reads (30%) | catalogued as rs938270992; called by muse, mutect2, varscan2
- SLC25A5 | c.-42C>T | 5'UTR (SNP) | VAF 178/239 reads (74%) | catalogued as rs761817456; called by muse, mutect2, varscan2
- SMOC1 | c.584-35C>A | Intron (SNP) | VAF 154/503 reads (31%) | called by muse, mutect2, varscan2
- SMPD4BP | n.1404A>T | RNA (SNP) | VAF 73/231 reads (32%) | called by muse, mutect2, varscan2
- SNORD115-41 | n.72C>G | RNA (SNP) | VAF 90/290 reads (31%) | called by muse, mutect2, varscan2
- THSD7B | c.140-65507G>T | Intron (SNP) | VAF 55/163 reads (34%) | called by muse, mutect2, varscan2
- TTC9C | c.-130dup | 5'UTR (INS) | VAF 78/136 reads (57%) | catalogued as rs898887777; called by mutect2, pindel, varscan2
- VAPB | c.*2767G>A | 3'UTR (SNP) | VAF 62/162 reads (38%) | catalogued as rs567568449; called by muse, mutect2, varscan2
- ZEB2 | c.73+3915T>A | Intron (SNP) | VAF 52/144 reads (36%) | called by muse, mutect2, varscan2
